Somatic mutation profile of tumor specimen TCGA-T1-A6J8-01A (aliquot TCGA-T1-A6J8-01A-11D-A32G-10) from TCGA case TCGA-T1-A6J8, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; Tumor grade: G2; Age at diagnosis: 68.0 years (24,853 days).
Specimen TCGA-T1-A6J8-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 11617a37-7f9c-4e74-918c-c8d700744b59.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-T1-A6J8-10A (Blood Derived Normal), aliquot TCGA-T1-A6J8-10A-01D-A32G-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0bc9b72d-daa8-48fd-bd94-8eedc3cc31df

The open-access MAF lists 91 somatic variants for this specimen: 69 protein-altering or splice-affecting, 22 silent.
By variant classification: Missense Mutation 58, Silent 22, Frame Shift Del 7, Splice Site 2, Nonsense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.560-1G>A p.X187_splice | Splice Site (SNP) | VAF 41/68 reads (60%) | hotspot (GDC flag); catalogued as rs1202793339, CD043957, CS011574, CS083991, COSV52662318, COSV52676510, COSV52683087, COSV52690533; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- AACS | c.343G>T p.A115S | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99908279; called by muse, mutect2, varscan2
- ABCA13 | c.8521A>G p.T2841A | Missense Mutation (SNP) | VAF 54/148 reads (36%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as COSV101447204; called by muse, mutect2, varscan2
- ABCC4 | c.1037T>A p.I346N | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV100972763; called by muse, mutect2, varscan2
- ADAMTS2 | c.3398G>T p.R1133L | Missense Mutation (SNP) | VAF 105/229 reads (46%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV52397039, COSV99283778; called by muse, mutect2, varscan2
- ARF5 | c.280A>G p.S94G | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.882); catalogued as COSV99133929; called by muse, mutect2, varscan2
- ARHGAP33 | c.1256A>G p.E419G | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.815); catalogued as COSV99139947; called by muse, mutect2, varscan2
- ARMH3 | c.562A>T p.I188L | Missense Mutation (SNP) | VAF 49/196 reads (25%) | SIFT tolerated (0.45); PolyPhen benign (0.048); catalogued as COSV100899041; called by muse, mutect2, varscan2
- ASPHD1 | c.407C>A p.P136H | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV100435829; called by muse, mutect2, varscan2
- BCHE | c.127G>A p.G43R | Missense Mutation (SNP) | VAF 24/203 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1330735515, COSV100012972; called by muse, mutect2, varscan2
- BID | c.11G>A p.G4D | Missense Mutation (SNP) | VAF 23/30 reads (77%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.059); catalogued as COSV100433864; called by muse, mutect2, varscan2
- BIRC6 | c.14455C>A p.P4819T | Missense Mutation (SNP) | VAF 29/79 reads (37%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.281); catalogued as COSV101428844; called by muse, mutect2, varscan2
- C10orf71 | c.383T>C p.V128A | Missense Mutation (SNP) | VAF 33/84 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.106); catalogued as COSV100110627; called by muse, mutect2, varscan2
- C2orf68 | c.383A>G p.D128G | Missense Mutation (SNP) | VAF 35/89 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV100108330; called by muse, mutect2, varscan2
- CCT7 | c.1502A>G p.N501S | Missense Mutation (SNP) | VAF 78/188 reads (41%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as rs760632421, COSV99241169; called by muse, mutect2, varscan2
- CDH10 | c.2179G>A p.A727T | Missense Mutation (SNP) | VAF 14/110 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.918); catalogued as rs763581492, COSV52589090, COSV52594161; called by muse, mutect2
- CGNL1 | c.47G>T p.G16V | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.957); catalogued as COSV99849115; called by muse, mutect2, varscan2
- CRIP2 | c.571G>T p.G191C | Missense Mutation (SNP) | VAF 31/73 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV100231765; called by muse, mutect2, varscan2
- CYP2A7 | c.609C>A p.S203R | Missense Mutation (SNP) | VAF 42/100 reads (42%) | SIFT tolerated (0.88); PolyPhen benign (0.001); catalogued as COSV99394499; called by muse, mutect2, varscan2
- ERBB4 | c.1026G>C p.L342F | Missense Mutation (SNP) | VAF 68/133 reads (51%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.999); catalogued as COSV99632326; called by muse, mutect2, varscan2
- GABPB1 | c.143A>G p.Y48C | Missense Mutation (SNP) | VAF 38/108 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV99590098; called by muse, mutect2, varscan2
- GPHB5 | c.104G>T p.G35V | Missense Mutation (SNP) | VAF 42/101 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100030248, COSV58487500; called by muse, mutect2, varscan2
- GRM3 | c.1826C>A p.A609E | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100862873; called by muse, mutect2, varscan2
- HDAC4 | c.23-1G>C p.X8_splice | Splice Site (SNP) | VAF 78/155 reads (50%) | catalogued as COSV100614196; called by muse, mutect2, varscan2
- HERC1 | c.4987A>T p.R1663* | Nonsense Mutation (SNP) | VAF 54/133 reads (41%) | catalogued as COSV101496893; called by muse, mutect2, varscan2
- HES1 | c.128A>T p.E43V | Missense Mutation (SNP) | VAF 83/181 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99220590; called by muse, mutect2, varscan2
- HMGB4 | c.185C>A p.A62D | Missense Mutation (SNP) | VAF 17/112 reads (15%) | SIFT tolerated (1); PolyPhen possibly damaging (0.653); catalogued as COSV53920739, COSV99595016; called by muse, mutect2, varscan2
- HNF1A | c.113T>C p.L38P | Missense Mutation (SNP) | VAF 44/124 reads (35%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.012); catalogued as COSV99982985; called by muse, mutect2
- LAMB4 | c.2950T>C p.C984R | Missense Mutation (SNP) | VAF 88/231 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99225552; called by muse, mutect2, varscan2
- LNPEP | c.2587G>A p.V863M | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99183607; called by muse, mutect2, varscan2
- LRRC55 | c.116C>T p.P39L | Missense Mutation (SNP) | VAF 34/84 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101546784; called by muse, mutect2, varscan2
- LTBP1 | c.1664A>G p.Q555R (on ENST00000404816 / NM_206943.4; = p.Q229R on NM_000627.4) | Missense Mutation (SNP) | VAF 32/95 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.844); catalogued as COSV100617919; called by muse, mutect2, varscan2
- MACC1 | c.1442A>G p.H481R | Missense Mutation (SNP) | VAF 52/119 reads (44%) | SIFT tolerated (0.24); PolyPhen benign (0.302); catalogued as COSV100256266; called by muse, mutect2, varscan2
- MAPK14 | c.937G>A p.D313N | Missense Mutation (SNP) | VAF 47/120 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV57695256, COSV57698287; called by muse, mutect2, varscan2
- MLLT10 | c.243A>T p.R81S | Missense Mutation (SNP) | VAF 34/168 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV100308763; called by muse, varscan2
- MYO18B | c.7010C>G p.T2337R | Missense Mutation (SNP) | VAF 22/34 reads (65%) | SIFT tolerated (0.35); PolyPhen benign (0.387); catalogued as COSV100125100; called by muse, mutect2, varscan2
- NAT8 | c.118C>A p.P40T | Missense Mutation (SNP) | VAF 33/80 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV99722077; called by muse, mutect2, varscan2
- NCOA6 | c.4991C>A p.S1664Y | Missense Mutation (SNP) | VAF 30/108 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.054); catalogued as COSV100750335; called by muse, mutect2, varscan2
- OLA1 | c.22G>A p.D8N | Missense Mutation (SNP) | VAF 28/272 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV99506810; called by muse, mutect2, varscan2
- OR5L2 | c.172C>A p.P58T | Missense Mutation (SNP) | VAF 102/258 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV65723904, COSV65725055; called by muse, mutect2, varscan2
- PCDHA5 | c.2155G>A p.A719T | Missense Mutation (SNP) | VAF 17/127 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.734); catalogued as rs1554129666, COSV65350345; called by muse, mutect2, varscan2
- PCLO | c.12583C>A p.L4195I | Missense Mutation (SNP) | VAF 62/174 reads (36%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.988); catalogued as COSV100437563, COSV61655245; called by muse, mutect2, varscan2
- PDZD9 | c.520C>T p.H174Y (on ENST00000424898 / NM_001363519.1; = p.H114Y on NM_173806.4) | Missense Mutation (SNP) | VAF 54/235 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99193386; called by muse, mutect2, varscan2
- PITPNM2 | c.139C>T p.P47S | Missense Mutation (SNP) | VAF 60/133 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV99759623; called by muse, mutect2, varscan2
- PRKX | c.882del p.N295Mfs*3 | Frame Shift Del (DEL) | VAF 98/128 reads (77%) | catalogued as COSV99467570; called by mutect2, varscan2
- PROSER1 | c.2594C>A p.S865Y | Missense Mutation (SNP) | VAF 73/184 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.165); catalogued as COSV100613031; called by muse, mutect2, varscan2
- PRX | c.1271C>T p.S424F | Missense Mutation (SNP) | VAF 49/131 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as COSV52530595; called by muse, mutect2, varscan2
- PSTPIP1 | c.115A>T p.M39L | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as COSV99143966; called by muse, mutect2, varscan2
- PTPRO | c.3338G>C p.S1113T (on ENST00000281171 / NM_030667.3; = p.S1085T on NM_002848.4) | Missense Mutation (SNP) | VAF 23/87 reads (26%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.977); catalogued as COSV99841700; called by muse, mutect2, varscan2
- SEMA3A | c.1661G>T p.R554I | Missense Mutation (SNP) | VAF 126/328 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.677); catalogued as COSV54879588, COSV99547892; called by muse, varscan2
- SLC24A3 | c.1325C>T p.S442L | Missense Mutation (SNP) | VAF 47/112 reads (42%) | SIFT tolerated (0.14); PolyPhen benign (0.045); catalogued as rs751279859, COSV60116231; called by muse, mutect2, varscan2
- SPTBN2 | c.1309C>T p.R437W | Missense Mutation (SNP) | VAF 31/138 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100020439; called by muse, mutect2, varscan2
- SRPK1 | c.1747G>T p.A583S | Missense Mutation (SNP) | VAF 37/93 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.399); catalogued as rs1463826128, COSV100644450; called by muse, mutect2, varscan2
- TCHP | c.274C>T p.Q92* | Nonsense Mutation (SNP) | VAF 4/60 reads (7%) | catalogued as COSV57165634; called by muse, mutect2
- TMEM63C | c.1627G>A p.A543T | Missense Mutation (SNP) | VAF 37/99 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs180758756, COSV53601664; called by muse, mutect2, varscan2
- TOP2A | c.4322C>A p.T1441N | Missense Mutation (SNP) | VAF 100/229 reads (44%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.057); catalogued as COSV101352318; called by muse, mutect2, varscan2
- TRA2B | c.400C>A p.L134I | Missense Mutation (SNP) | VAF 48/133 reads (36%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.836); catalogued as COSV99373337; called by muse, mutect2, varscan2
- TRIM71 | c.1973G>A p.G658D | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as COSV101070497; called by muse, mutect2, varscan2
- UBR4 | c.1552A>T p.I518L | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV100921809; called by muse, mutect2, varscan2
- UNC13C | c.2431G>T p.V811L | Missense Mutation (SNP) | VAF 33/78 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); catalogued as COSV99522750; called by muse, varscan2
- USP36 | c.974C>G p.T325S | Missense Mutation (SNP) | VAF 51/152 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV100361809; called by muse, mutect2, varscan2
- ZNF804B | c.162C>A p.N54K | Missense Mutation (SNP) | VAF 38/108 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs745631086, COSV100306077, COSV60817945; called by muse, mutect2, varscan2
- CACNA1G | c.1790del p.P597Lfs*6 | Frame Shift Del (DEL) | VAF 43/115 reads (37%) | called by mutect2, pindel, varscan2
- CLK3 | c.1360_1372del p.C454Qfs*2 (on ENST00000395066 / NM_001130028.1; = p.C306Qfs*2 on NM_003992.4) | Frame Shift Del (DEL) | VAF 38/100 reads (38%) | called by pindel, varscan2
- COL27A1 | c.1654del p.R552Gfs*17 | Frame Shift Del (DEL) | VAF 18/37 reads (49%) | called by mutect2, pindel, varscan2
- GCN1 | c.4084_4088delinsC p.C1362Rfs*15 | Frame Shift Del (DEL) | VAF 28/67 reads (42%) | called by pindel, varscan2*
- PRKX | c.881C>A p.A294E | Missense Mutation (SNP) | VAF 100/126 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); called by mutect2, varscan2
- RELN | c.5530del p.E1844Kfs*3 | Frame Shift Del (DEL) | VAF 93/295 reads (32%) | called by mutect2, pindel, varscan2
- TJP1 | c.4616_4617del p.F1539* | Frame Shift Del (DEL) | VAF 96/292 reads (33%) | called by mutect2, pindel, varscan2
- ACSL6 | c.1692G>A p.Q564= (on ENST00000379240; = p.Q589= on NM_015256.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 8/155 reads (5%) | catalogued as COSV99734600; called by muse, mutect2
- AP3B2 | c.2925G>A p.G975= (on ENST00000261722; = p.G969= on NM_004644.5) | Silent (SNP) | VAF 48/102 reads (47%) | catalogued as rs1383075061, COSV99916999; called by muse, mutect2, varscan2
- ARNT2 | c.1761A>T p.P587= | Silent (SNP) | VAF 76/180 reads (42%) | catalogued as COSV100309513; called by muse, mutect2, varscan2
- AUTS2 | c.576A>T p.G192= | Silent (SNP) | VAF 54/166 reads (33%) | catalogued as COSV100719511; called by muse, mutect2, varscan2
- COL23A1 | c.1332G>T p.S444= | Silent (SNP) | VAF 32/80 reads (40%) | catalogued as COSV101179697; called by muse, mutect2, varscan2
- CRHBP | c.219C>G p.T73= | Silent (SNP) | VAF 32/93 reads (34%) | catalogued as COSV57188914, COSV99169534; called by muse, mutect2, varscan2
- IGFL4 | c.90C>T p.C30= | Silent (SNP) | VAF 44/98 reads (45%) | catalogued as COSV100890864; called by muse, mutect2, varscan2
- MAPK6 | c.2136A>T p.T712= | Silent (SNP) | VAF 62/171 reads (36%) | catalogued as rs201094277, COSV99959422; called by muse, mutect2, varscan2
- MED13 | c.1467C>T p.D489= | Silent (SNP) | VAF 34/346 reads (10%) | catalogued as rs762008104, COSV101181374, COSV67267897; called by muse, mutect2
- MFN1 | c.1080G>T p.L360= | Silent (SNP) | VAF 68/219 reads (31%) | catalogued as COSV99764697; called by muse, mutect2, varscan2
- MLXIPL | c.2286G>T p.T762= | Silent (SNP) | VAF 46/119 reads (39%) | catalogued as COSV57667127; called by muse, mutect2, varscan2
- MSH4 | c.240T>G p.A80= | Silent (SNP) | VAF 12/36 reads (33%) | catalogued as COSV99592505; called by muse, varscan2
- MVP | c.681G>C p.L227= | Silent (SNP) | VAF 10/41 reads (24%) | catalogued as rs1416679222, COSV100651715; called by muse, mutect2, varscan2
- NTF3 | c.702C>T p.L234= | Silent (SNP) | VAF 33/53 reads (62%) | catalogued as COSV100451150; called by muse, mutect2, varscan2
- OR13A1 | c.489C>A p.A163= | Silent (SNP) | VAF 15/54 reads (28%) | catalogued as COSV100981088; called by muse, mutect2, varscan2
- PCDH15 | c.4437A>G p.Q1479= | Silent (SNP) | VAF 53/125 reads (42%) | catalogued as rs141623033, COSV100227308; called by muse, mutect2, varscan2
- RAB1B | c.51A>C p.S17= | Silent (SNP) | VAF 48/123 reads (39%) | catalogued as COSV100270874; called by muse, mutect2, varscan2
- SLC22A14 | c.378C>T p.G126= | Silent (SNP) | VAF 23/106 reads (22%) | catalogued as rs778744185, COSV99828349; called by muse, mutect2, varscan2
- SLC24A2 | c.1158C>A p.L386= | Silent (SNP) | VAF 61/97 reads (63%) | catalogued as COSV99647418; called by muse, mutect2, varscan2
- UNC13C | c.2430A>T p.V810= | Silent (SNP) | VAF 33/79 reads (42%) | catalogued as COSV99522747; called by muse, varscan2
- WDR17 | c.3297A>G p.V1099= | Silent (SNP) | VAF 21/197 reads (11%) | catalogued as COSV99708249; called by muse, mutect2, varscan2
- ZFP36L1 | c.954C>T p.S318= | Silent (SNP) | VAF 41/87 reads (47%) | catalogued as COSV100322905; called by muse, mutect2, varscan2
